CMI case MBCProject_2991 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/8ebbcdbf-7c20-4858-a5d8-9b9cebafe21f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 65.1 years (23,767 days).

Biospecimens (7 samples)
- Sample MBCProject_2991_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCProject_2991_T1A_RNA, MBCProject_2991_T1A_WES, MBCProject_2991_T1B_RNA, MBCProject_2991_T1B_WES, MBCProject_2991_T2_RNA, MBCProject_2991_T2_WES (6 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
